CPTAC case C3L-06070 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b572a483-5a48-4d97-a4af-6eefd1708730

Demographics
Sex at birth: female; Race: white; Year of birth: 1968; Vital status: Dead; Days to death: 159 days; Year of death: 2019; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.7 years (18,514 days); Year of diagnosis: 2019; Days to last known disease status: 159 days; Progression or recurrence: no; Days to last follow up: 369 days (1.0 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 369 days (1.0 years); Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 369 days (1.0 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 111 kg; Height: 165 cm; BMI: 40.77.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 12.5; Cigarettes per day: 10; Tobacco smoking onset year: 1993; Tobacco smoking quit year: 2018; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 25.

Biospecimens (5 samples)
- Samples C3L-06070-51, C3L-06070-52, C3L-06070-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-06070-54, C3L-06070-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 10 days; Time between excision and freezing: 380 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
